Somatic mutation profile of tumor specimen TCGA-32-1970-01A (aliquot TCGA-32-1970-01A-01W-0837-08) from TCGA case TCGA-32-1970, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,613 days).
Specimen TCGA-32-1970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 678cf775-123d-4229-a7ac-44db20336bbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1970-10A (Blood Derived Normal), aliquot TCGA-32-1970-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38c3188d-6a13-404e-8c41-0f11ff3a8fe3

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 20, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 1, Splice Region 1, 3'Flank 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 938/1933 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 51/57 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAP2 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58749185; called by muse, mutect2, varscan2
- ACTBL2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.493); catalogued as rs756215581, COSV70660975; called by muse, mutect2, varscan2
- ASPM | c.9410C>A p.A3137D | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54124335; called by muse, mutect2, varscan2
- AXIN2 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs771809149, COSV61055414; called by muse, mutect2, varscan2
- CCZ1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761962272, COSV100382890; called by mutect2, varscan2
- CDK13 | c.3088C>T p.Q1030* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as COSV51696300; called by muse, mutect2, varscan2
- CEL | c.1411G>A p.A471T (on ENST00000673714; = p.A468T on NM_001807.6) | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs777913068, COSV60826235; called by muse, mutect2
- CEP104 | c.2715C>G p.S905R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65516059; called by muse, mutect2, varscan2
- CEP128 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200105295, COSV53672384; called by muse, mutect2, varscan2
- COPB1 | c.1213-2A>T p.X405_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as rs753555066; called by mutect2, varscan2
- CWF19L2 | c.2494G>A p.A832T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293944790, COSV56508314; called by muse, mutect2, varscan2
- EGFL6 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 221/254 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182977902, COSV63632763; called by muse, mutect2, varscan2
- EHD3 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV59029169; called by muse, mutect2
- ENPP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776304212, COSV50009900; called by muse, mutect2, varscan2
- FAM71B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs745867472, COSV57227431; called by muse, mutect2, varscan2
- FBXW11 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51605180; called by muse, mutect2, varscan2
- FFAR3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 97/672 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs757551373, COSV59908663; called by muse, mutect2, varscan2
- FLRT2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58136045; called by muse, mutect2, varscan2
- GATM | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV67540101; called by muse, mutect2, varscan2
- GCA | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as COSV52025032; called by muse, mutect2, varscan2
- GLS | c.735G>A p.K245= | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as COSV57839796; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 20/90 reads (22%) | catalogued as rs749150409; called by mutect2, varscan2
- GRM3 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1363070278, COSV64467002; called by muse, mutect2, varscan2
- GRM3 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 251/1037 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV64467011; called by muse, mutect2, varscan2
- HELZ2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs748068037, COSV64409001; called by muse, mutect2, varscan2
- HRNR | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 174/404 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs777994503, COSV64253956; called by muse, mutect2, varscan2
- ITIH5 | c.789C>A p.D263E | Missense Mutation (SNP) | VAF 192/261 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53659541; called by muse, mutect2, varscan2
- KLC4 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1304846100, COSV99431637; called by muse, mutect2
- MAGI2 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV62633216; called by muse, mutect2, varscan2
- MEGF11 | c.2837C>A p.T946K | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.261); catalogued as COSV56544427; called by muse, mutect2, varscan2
- METTL9 | c.166-2A>T p.X56_splice | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as rs754980571; called by mutect2, varscan2
- NOTCH3 | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs150941674; called by muse, varscan2
- OR4B1 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 231/515 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58881927; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2, varscan2
- PCLO | c.7709C>T p.P2570L | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61615127; called by muse, mutect2, varscan2
- PGPEP1L | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 157/384 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs372203076; called by muse, mutect2, varscan2
- POLD4 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56744483; called by muse, mutect2, varscan2
- PRPF40B | c.1462C>T p.R488C (on ENST00000380281; = p.R482C on NM_012272.3) | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781235317, COSV56057621; called by muse, mutect2, varscan2
- PRRC2B | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs377155180; called by muse, varscan2
- PSPH | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 748/3346 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV51908839; called by muse, varscan2
- PTGFR | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 105/226 reads (46%) | catalogued as rs750752823, COSV66114248, COSV66115158; called by muse, mutect2, varscan2
- RANBP17 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs748673739, COSV66643784; called by muse, mutect2, varscan2
- RB1 | c.2336T>A p.L779* | Nonsense Mutation (SNP) | VAF 153/213 reads (72%) | catalogued as CS143547, COSV57295462; called by muse, mutect2, varscan2
- RBMS3 | c.1208C>G p.T403R (on ENST00000383767 / NM_001003793.3; = p.T387R on NM_014483.3) | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs143165101, COSV56131344; called by muse, mutect2, varscan2
- RNF31 | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV60725543; called by muse, mutect2
- SLC47A2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148775490; called by muse, mutect2, varscan2
- SNX20 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772636555, COSV56056544; called by muse, mutect2
- SOX6 | c.2087G>A p.R696H (on ENST00000528429 / NM_001145819.2; = p.R669H on NM_017508.3) | Missense Mutation (SNP) | VAF 71/378 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57036569; called by muse, mutect2, varscan2
- STEAP1 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51880880; called by muse, mutect2, varscan2
- TMEM132B | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs868065390, COSV54744303; called by muse, mutect2, varscan2
- TMEM219 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54243359; called by muse, mutect2, varscan2
- TNFRSF8 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 97/220 reads (44%) | catalogued as rs148756853; called by muse, mutect2, varscan2
- TRAV20 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs369305527; called by muse, mutect2, varscan2
- TRIM58 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 196/478 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1277659091, COSV63569037, COSV63570091; called by muse, mutect2, varscan2
- TTN | c.14672T>C p.I4891T (on ENST00000591111; = p.I3964T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/640 reads (3%) | PolyPhen benign (0.1); catalogued as COSV59878800; called by muse, mutect2
- UGGT1 | c.4157G>T p.C1386F | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52132227; called by muse, mutect2, varscan2
- ZNF107 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201135722, COSV61326756; called by muse, mutect2, varscan2
- ZNF229 | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 217/536 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs754516445, COSV52159418; called by muse, mutect2, varscan2
- ZNFX1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 85/428 reads (20%) | catalogued as COSV65573550; called by muse, mutect2, varscan2
- ANK1 | c.4841_4849del p.E1614_S1617delinsA | In Frame Del (DEL) | VAF 110/305 reads (36%) | called by mutect2, pindel, varscan2
- GEN1 | c.2515_2522delinsGAA p.K839Efs*2 | Frame Shift Del (DEL) | VAF 24/39 reads (62%) | called by mutect2*, pindel, varscan2*
- HMGXB4 | c.1784C>A p.A595D | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAF3 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C7 | c.2082G>A p.P694= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs367904690; called by muse, mutect2
- CCR9 | c.141G>A p.A47= (on ENST00000357632 / NM_031200.3; = p.A35= on NM_006641.4) | Silent (SNP) | VAF 233/435 reads (54%) | catalogued as rs372974725; called by muse, mutect2, varscan2
- CEP164 | c.432T>C p.L144= | Silent (SNP) | VAF 117/760 reads (15%) | called by mutect2, varscan2
- CPNE2 | c.639C>T p.P213= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV51960785, COSV99321227; called by muse, mutect2, varscan2
- CYP2C18 | c.259C>T p.L87= | Silent (SNP) | VAF 481/665 reads (72%) | catalogued as COSV53669588; called by muse, mutect2, varscan2
- DHRS13 | c.402G>A p.A134= | Silent (SNP) | VAF 76/182 reads (42%) | catalogued as rs549688711, COSV60453041; called by muse, mutect2, varscan2
- DPH2 | c.963G>T p.R321= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as COSV52542460, COSV52542500; called by muse, mutect2, varscan2
- DPP10 | c.843G>A p.P281= | Silent (SNP) | VAF 253/629 reads (40%) | catalogued as rs146251151, COSV100071178; called by muse, mutect2, varscan2
- EIF4G1 | c.2640G>T p.L880= (on ENST00000346169 / NM_198241.3; = p.L685= on NM_004953.5) | Silent (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- FRG2 | c.384C>G p.S128= | Silent (SNP) | VAF 71/149 reads (48%) | called by muse, mutect2, varscan2
- KRTAP4-5 | c.213T>C p.C71= | Silent (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- LY6G6D | c.216C>T p.V72= | Silent (SNP) | VAF 68/1891 reads (4%) | catalogued as rs1207698390, COSV65419689; called by muse, mutect2
- MRGPRX3 | c.93G>A p.T31= | Silent (SNP) | VAF 333/800 reads (42%) | catalogued as rs752591852, COSV66933165; called by muse, mutect2, varscan2
- MS4A3 | c.558C>T p.C186= | Silent (SNP) | VAF 277/743 reads (37%) | catalogued as rs778541342, COSV53934779; called by muse, mutect2, varscan2
- MTNR1B | c.471C>A p.T157= | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as COSV57065231; called by muse, mutect2, varscan2
- NEURL4 | c.4374C>T p.F1458= | Silent (SNP) | VAF 125/164 reads (76%) | catalogued as rs752327546, COSV59746958; called by muse, mutect2, varscan2
- OR13C9 | c.933G>A p.P311= | Silent (SNP) | VAF 121/429 reads (28%) | catalogued as rs761736284, COSV52240578; called by muse, mutect2, varscan2
- OR1S1 | c.165C>T p.N55= | Silent (SNP) | VAF 195/506 reads (39%) | catalogued as rs199668390, COSV58705936; called by muse, mutect2, varscan2
- OR2G6 | c.453C>T p.S151= | Silent (SNP) | VAF 89/218 reads (41%) | catalogued as rs774470186, COSV100598332, COSV58573644; called by muse, mutect2, varscan2
- PCDHGB1 | c.252C>T p.N84= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV53896243; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37167200 T>A | 3'Flank (SNP) | VAF 13/59 reads (22%) | catalogued as COSV57051713; called by muse, mutect2, varscan2
- NACA | c.71-1199dup | Intron (INS) | VAF 30/74 reads (41%) | catalogued as rs1411787469; called by mutect2, pindel, varscan2
